Somatic mutation profile of tumor specimen TARGET-30-PAUZAE-01A (aliquot TARGET-30-PAUZAE-01A-01D) from TARGET case TARGET-30-PAUZAE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.5 years (1,276 days).
Specimen TARGET-30-PAUZAE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e63d6394-c872-4f9f-b5f6-aa9b8ce9547d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUZAE-10A (Blood Derived Normal), aliquot TARGET-30-PAUZAE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e4cdde8-1b82-49d7-b181-46261afbc3b2

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100486542; called by muse, mutect2, varscan2
- CPM | c.1122A>G p.T374= | Silent (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
